Somatic mutation profile of tumor specimen C3N-01948-01 (aliquot CPT0163650006) from CPTAC case C3N-01948, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 55.7 years (20,359 days).
Specimen C3N-01948-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 894c6223-494b-40bb-bfb7-1388d2db1ff0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01948-31 (Blood Derived Normal), aliquot CPT0163710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f688b7a0-b886-47ae-a684-d1d69950420d

The open-access MAF lists 77 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 15, Nonsense Mutation 7, Intron 5, Frame Shift Del 2, 3'UTR 2, 5'Flank 1, Splice Site 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO7A | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781811444, COSV68685635; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 124/743 reads (17%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.4153C>T p.R1385* | Nonsense Mutation (SNP) | VAF 17/198 reads (9%) | catalogued as rs1479476888, COSV60681342; called by muse, mutect2
- ADAMTS6 | c.15G>C p.W5C | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs902104612, COSV66863740, COSV66865944; called by muse, mutect2
- AHNAK | c.5714T>G p.L1905W | Missense Mutation (SNP) | VAF 18/590 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.785); catalogued as rs1446260856; called by muse, mutect2
- ATP10A | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 50/686 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755196001, COSV63516408; called by muse, mutect2
- ATP1A2 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 46/642 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.19); catalogued as rs765021457, COSV63403673; called by muse, mutect2
- C12orf40 | c.942G>C p.R314S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV61132688; called by muse, mutect2
- DCAF12L1 | c.916T>C p.F306L | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100948336; called by muse, mutect2
- DENND4C | c.4166C>G p.S1389C (on ENST00000434457 / NM_001330640.2; = p.S1340C on NM_017925.7) | Missense Mutation (SNP) | VAF 61/338 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100727418; called by muse, mutect2, varscan2
- EPHB1 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 28/539 reads (5%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.994); catalogued as rs761687482; called by muse, mutect2
- EPS15L1 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 12/274 reads (4%) | catalogued as rs866290023; called by muse, mutect2
- GATAD2B | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 20/598 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64084235; called by muse, mutect2
- GCN1 | c.3899A>C p.E1300A | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56107647; called by muse, mutect2
- GOLGA4 | c.1119G>A p.M373I | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs966603099; called by muse, mutect2
- GZMM | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 13/318 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.426); catalogued as COSV52743100; called by muse, mutect2
- IGSF10 | c.6995A>G p.E2332G | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as rs200423886; called by muse, mutect2
- JPH4 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 5/100 reads (5%) | catalogued as COSV58111100; called by muse, mutect2
- KLHL11 | c.1810A>G p.I604V | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1487504227; called by muse, mutect2, varscan2
- LRP1B | c.10337C>T p.T3446M | Missense Mutation (SNP) | VAF 23/298 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as rs748759183, COSV67182342; called by muse, mutect2
- PCNX3 | c.4943A>G p.K1648R | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1338043400; called by muse, mutect2
- RBL2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs1399900721; called by muse, mutect2
- ZNF626 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101656994; called by muse, mutect2
- ANKRD1 | c.28G>T p.V10F | Missense Mutation (SNP) | VAF 27/596 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARHGEF1 | c.1268A>T p.E423V | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BPIFB6 | c.1329G>C p.E443D | Missense Mutation (SNP) | VAF 24/419 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- CLEC1A | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.36); called by muse, mutect2
- CMTM2 | c.595C>G p.Q199E | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CORIN | c.463A>C p.T155P | Missense Mutation (SNP) | VAF 21/360 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2
- CTNND1 | c.1894+1G>A p.X632_splice | Splice Site (SNP) | VAF 17/200 reads (9%) | called by muse, mutect2
- DOC2B | c.515_517delinsT p.P172Lfs*4 | Frame Shift Del (DEL) | VAF 36/216 reads (17%) | called by pindel, varscan2*
- DYRK1A | c.1952G>A p.S651N | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); called by muse, mutect2
- FARP2 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 24/364 reads (7%) | called by muse, mutect2
- GHR | c.410A>G p.D137G | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- HS3ST5 | c.565G>C p.A189P | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2
- LRRK2 | c.1732G>T p.E578* | Nonsense Mutation (SNP) | VAF 15/247 reads (6%) | called by muse, mutect2
- LYVE1 | c.919T>C p.S307P | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OGT | c.1972A>G p.I658V | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2
- OR10G7 | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- PKD1 | c.6362G>T p.R2121L | Missense Mutation (SNP) | VAF 38/683 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.028); called by muse, mutect2
- PKP4 | c.2909A>G p.K970R | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.092); called by muse, mutect2
- RAB5C | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- RNF213 | c.7753C>G p.L2585V | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC2A8 | c.1210C>T p.H404Y | Missense Mutation (SNP) | VAF 78/407 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- STK25 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 32/325 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.198); called by muse, mutect2
- STRN3 | c.2372C>T p.A791V (on ENST00000357479 / NM_001083893.2; = p.A707V on NM_014574.4) | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- STXBP5L | c.1314del p.K438Nfs*36 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- TOR4A | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 54/368 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.94805T>C p.I31602T (on ENST00000591111; = p.I24178T on NM_003319.4) | Missense Mutation (SNP) | VAF 10/156 reads (6%) | PolyPhen benign (0.009); called by muse, mutect2
- VAT1L | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 32/418 reads (8%) | called by muse, mutect2
- WDR27 | c.292A>G p.M98V | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- ZNF600 | c.1024A>T p.N342Y | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- EVL | c.471C>T p.T157= (on ENST00000402714 / NM_001330221.2; = p.T159= on NM_016337.3) | Silent (SNP) | VAF 19/267 reads (7%) | called by muse, mutect2
- FARP2 | c.447G>T p.L149= | Silent (SNP) | VAF 24/362 reads (7%) | called by muse, mutect2
- HCFC1 | c.4116C>T p.S1372= | Silent (SNP) | VAF 9/107 reads (8%) | catalogued as rs782247716, COSV60071364, COSV60079354; called by muse, mutect2
- INSL4 | c.234C>T p.A78= | Silent (SNP) | VAF 26/265 reads (10%) | called by muse, mutect2
- LSAMP | c.123A>G p.E41= | Silent (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- MUC17 | c.7719C>T p.S2573= | Silent (SNP) | VAF 11/211 reads (5%) | called by muse, mutect2
- PRX | c.2988C>T p.L996= | Silent (SNP) | VAF 20/308 reads (6%) | called by muse, mutect2
- RANBP2 | c.2865G>A p.S955= | Silent (SNP) | VAF 26/468 reads (6%) | catalogued as rs763628368; called by muse, mutect2
- RELN | c.9705C>T p.C3235= | Silent (SNP) | VAF 50/620 reads (8%) | catalogued as COSV100634534; called by muse, mutect2
- RHBDD1 | c.183G>A p.Q61= | Silent (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- RNF113B | c.846G>A p.E282= | Silent (SNP) | VAF 45/390 reads (12%) | called by muse, varscan2
- SLC2A8 | c.1209G>T p.L403= | Silent (SNP) | VAF 79/405 reads (20%) | called by muse, mutect2, varscan2
- SPTY2D1 | c.411A>T p.A137= | Silent (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- TARS3 | c.99G>A p.R33= | Silent (SNP) | VAF 34/458 reads (7%) | called by muse, mutect2
- TRBV3-1 | c.255T>A p.P85= | Silent (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- AOC4P | n.460G>A | RNA (SNP) | VAF 22/326 reads (7%) | catalogued as rs748461244; called by muse, mutect2
- ARHGAP21 | c.4150+764A>G | Intron (SNP) | VAF 17/213 reads (8%) | catalogued as rs765436314; called by muse, mutect2
- C19orf47 | c.130+23A>T | Intron (SNP) | VAF 17/184 reads (9%) | called by muse, mutect2
- HAND2-AS1 | n.512+1208C>T | Intron (SNP) | VAF 19/252 reads (8%) | catalogued as rs1421684570; called by muse, mutect2
- KLHL1 | c.*4A>T | 3'UTR (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- NTRK2 | c.*18C>T | 3'UTR (SNP) | VAF 32/555 reads (6%) | called by muse, mutect2
- PRICKLE1 | c.1640-9C>T | Intron (SNP) | VAF 18/296 reads (6%) | called by muse, mutect2
- SNORD116-17 | chr15:25088031 C>A | 3'Flank (SNP) | VAF 20/204 reads (10%) | called by muse, mutect2
- SZT2 | c.498+4992A>G | Intron (SNP) | VAF 5/45 reads (11%) | catalogued as rs1223039352; called by muse, mutect2, varscan2
- ZBTB7B | chr1:155010923 T>A | 5'Flank (SNP) | VAF 25/394 reads (6%) | called by muse, mutect2
